Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA34, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA34-01A (Primary Tumor).

Female

Surgery Date:

DIAGNOSIS:

A. Liver, segment VI, wedge resection: Invasive grade 2 (of 4) cholangiocarcinoma forming a single, sclerotic mass (4.7 x 4.3 x 3.5 cm) with gross evidence of needle tract effect. The tumor is confined to the hepatic parenchyma. The hepatic parenchymal resection margin is negative for tumor (tumor free margin, 0.7 cm).

The intrahepatic bile duct margin is negative for invasive carcinoma and carcinoma in situ (1.0 cm). Major vessel invasion is absent. Microscopic invasion is absent. The background liver shows necrotizing granulomatous inflammation, presumably biopsy effect.

ICD-O3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

JW 3/8/14

Source: NCI Genomic Data Commons file 6b299f95-e91c-405c-a5fc-1753f2c698a7 (TCGA-W5-AA34.36EAF28B-5091-4C1A-8BA6-D18C0407FC47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).